Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UL-01A (Primary Tumor).

[page 1 of 2]
100-0-3

adenocarcinoma, endometrial, NOS 8380/3

Site: Endometrium 054-1

h 5/1/11

Surgical Pathology Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

History/Clinical Dx: Atypical endometrial cancer

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

DIAGNOSIS:

Uterus, cervix, tubes, and ovaries: ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:

Total abdominal hysterectomy with bilateral salpingo-oophorectomy

Histologic type:

Predominantly endometrioid with villoglandular foci

Histologic grade(FIGO):

Grade 1

Nuclear grade:

Grade 1

Tumor size:

1.5 x 1.0 x 0.5 cm

Extent of invasion:

No myometrial invasion identified

Lymphovascular invasion:

Not identified

Serosa:

Not involved

Parametrium:

Not identified

Cervical involvement:

Not involved

Right adnexa:

No significant histopathology

Left adnexa:

No significant histopathology

Other findings:

Endometrial polyps

Comments:

has reviewed this case and concurs.

Intraoperative Consultation:

Frozen Section Interpretation: No myometrial invasion

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing this report. This test was developed and its performance characteristics determined in-house and/or approved by the U.S. Food and Drug Administration. The FDA has determined that such reagents or reagents are not necessary. This test is used for clinical purposes. It is not intended for use as a diagnostic or for research. The laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

Gross Description

Received fresh labeled "cervix, uterus, bilateral tubes and ovaries" is a previously opened uterus with attached cervix and bilateral adnexa with a combined weight of 136 gms. The uterus measures 9.0 x 7.0 x 3.0 cm and the attached cervix measures 3.0 cm in length by 2.5 cm in diameter. The right ovary measures 2.5 x 2.0 x 1.0 cm and the right fallopian tube measures 4.0 cm in length by 0.5 cm in diameter. The left ovary measures 3.0 x 1.5 x 1.0 cm and the left fallopian tube measures 5.5 cm in length by 0.5 cm in diameter. The ectocervix appears pink-tan and unremarkable. The endocervical canal appears unremarkable. The endometrial cavity contains two polypoid red-tan tissue measuring up to 0.7 x 0.5 x 0.3 cm located on the posterior aspect of the endometrium and also on the anterior aspect. Towards the lower uterine segment there is an exophytic pink-tan mass measuring 1.5 x 1.0 x 0.5 cm with papillary projections. There is no myometrial invasion grossly identified. A portion of the mass is submitted for frozen section. The endometrium measures 0.1 cm in thickness. The myometrium measures 2.5 cm in thickness and appears partly trabeculated. The right ovary contains a 0.5 cm trabecular cyst. The remaining ovarian parenchyma appears unremarkable. The right ovary is interrupted by a previous tubal ligation otherwise unremarkable. The left ovary contains a 0.7 cm hemorrhagic cyst. The remaining ovarian parenchyma appears unremarkable. The left fallopian tube is interrupted by previous tubal ligation with multiple paratubal cysts measuring up to 0.3 cm in greatest dimension. Representative sections submitted as follows:

KEY TO CASSETTES:

- | | | |
|-------|---|---------------------------|
| 1 | - | Frozen section |
| 2&3 | - | Cervix |
| 4 | - | Lower uterine segment |
| 5-8: | - | Exophytic mass |
| 9&10 | - | Endomyometrium with polyp |
| 11&12 | - | Myometrium and serosa |
| 13 | - | Right adnexa |
| 14 | - | Left adnexa |

Microscopic Description

The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 0be9776d-57af-425e-980d-a8fc497a1609 (TCGA-BS-A0UL.323FC36E-D8E3-4F6B-A8FE-2040F3E44BB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).